CCDI case PBCIJU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/24520bd8-9c6a-4cab-85dc-3023f1889f60

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Mesenchymal chondrosarcoma: ICD-O-3 morphology code: 9240/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,401 days).

Biospecimens (3 samples)
- Sample 0DT3U8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT3UD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DT3UQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
